Somatic mutation profile of tumor specimen TCGA-G7-6792-01A (aliquot TCGA-G7-6792-01A-21D-1961-08) from TCGA case TCGA-G7-6792, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 40.1 years (14,664 days).
Specimen TCGA-G7-6792-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a80363b-bd16-46c4-9af5-45cb0b6eeba1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G7-6792-10A (Blood Derived Normal), aliquot TCGA-G7-6792-10A-01D-1962-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4719859-27f6-45f2-ba9d-9dad97007e93

The open-access MAF lists 33 somatic variants for this specimen: 21 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 17, Silent 12, Frame Shift Del 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGT | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV64184598; called by muse, mutect2, varscan2
- ARSI | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs1472402772, COSV60817441; called by muse, mutect2, varscan2
- CDAN1 | c.1553G>A p.G518D | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.813); catalogued as COSV62332057; called by muse, mutect2, varscan2
- CHCHD3 | c.195A>T p.R65S | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.428); catalogued as COSV52774876; called by muse, mutect2, varscan2
- CTDSPL | c.371C>G p.P124R (on ENST00000273179 / NM_001008392.2; = p.P113R on NM_005808.3) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56202094; called by muse, mutect2, varscan2
- DDX20 | c.944T>G p.F315C | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63831080; called by muse, mutect2, varscan2
- FYCO1 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.766); catalogued as rs747740941, COSV56116017; called by muse, mutect2, varscan2
- KLRK1 | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV53698563; called by muse, mutect2, varscan2
- KRBA1 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs756762203, COSV55441490; called by muse, mutect2, varscan2
- MGRN1 | c.1151C>A p.P384H | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52151025; called by muse, mutect2, varscan2
- PPFIBP2 | c.1696T>C p.W566R | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55077157; called by muse, mutect2, varscan2
- RAB3D | c.185A>T p.K62M | Missense Mutation (SNP) | VAF 114/355 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55791472; called by muse, mutect2, varscan2
- RBM27 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV54589904; called by muse, mutect2, varscan2
- STARD3 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 39/89 reads (44%) | catalogued as COSV59223653, COSV59225035; called by muse, mutect2, varscan2
- STK38L | c.792C>A p.N264K | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.405); catalogued as COSV66521480; called by muse, mutect2, varscan2
- TG | c.4468T>G p.C1490G | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55076519; called by muse, mutect2, varscan2
- TSC2 | c.5155G>A p.A1719T | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as rs201206500, COSV51912887; ClinVar: not provided / likely benign / uncertain significance; called by muse, mutect2, varscan2
- ZCCHC10 | c.481T>C p.S161P (on ENST00000509437 / NM_001300818.3; = p.S139P on NM_017665.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as COSV60772806; called by muse, mutect2, varscan2
- EPG5 | c.5287_5288dup p.M1764Sfs*4 | Frame Shift Ins (INS) | VAF 31/110 reads (28%) | called by mutect2, pindel, varscan2
- GNPTAB | c.1637del p.V546Gfs*26 | Frame Shift Del (DEL) | VAF 29/100 reads (29%) | called by mutect2, pindel, varscan2
- LACTB | c.385del p.V129Lfs*5 | Frame Shift Del (DEL) | VAF 29/97 reads (30%) | called by mutect2, pindel, varscan2
- ACACB | c.6111C>T p.L2037= | Silent (SNP) | VAF 85/218 reads (39%) | catalogued as COSV58134926; called by muse, mutect2, varscan2
- CST9L | c.219C>A p.I73= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV65407890; called by muse, mutect2, varscan2
- DSTYK | c.1621C>T p.L541= | Silent (SNP) | VAF 60/139 reads (43%) | catalogued as COSV65686534; called by muse, mutect2, varscan2
- ERLIN1 | c.948T>C p.Y316= | Silent (SNP) | VAF 49/125 reads (39%) | catalogued as rs1301810895, COSV64941155; called by muse, mutect2, varscan2
- F12 | c.1125C>T p.G375= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs759948258, COSV53691411; called by muse, mutect2, varscan2
- FNIP2 | c.3345A>G p.*1115= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as COSV52439902; called by muse, mutect2, varscan2
- KRR1 | c.960A>G p.A320= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV56991029; called by muse, mutect2, varscan2
- LEFTY1 | c.522C>T p.G174= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV55282975; called by muse, mutect2, varscan2
- NDUFAF4 | c.213T>C p.D71= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as COSV60214115; called by muse, mutect2, varscan2
- PTPRA | c.2100G>T p.V700= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as COSV53781775; called by muse, mutect2, varscan2
- TMC8 | c.1239T>G p.V413= | Silent (SNP) | VAF 70/187 reads (37%) | catalogued as COSV59209681; called by muse, mutect2, varscan2
- TRAV9-2 | c.108C>T p.A36= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1349925571; called by muse, mutect2, varscan2
